Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4TE, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4TE-01A (Primary Tumor).

[page 1 of 4]
urgical Pathology
REVISED REPORT (Revised information underlined)
Addendum/Procedure included
Requested By:

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: lung, (L) lower lobe 034.3

SLIDE DISPOSITION:

DIAGNOSIS:

- A. Lymph nodes, station 7, biopsy: Multiple (6) fragments of lymph nodes are negative for tumor.
- B. Lymph nodes, station 4L, biopsy: A single (1) lymph node is negative for tumor.
- C. Lymph nodes, station 4R, biopsy: A single (1) lymph node is negative for tumor.
- D. Lymph nodes, station 9L set #1, biopsy: A single (1) lymph node is negative for tumor.
- E. Lymph nodes, station 9L set #2, biopsy: Multiple (4) fragments of lymph nodes are negative for tumor.
- F. Lymph nodes, station 11L set #1, biopsy: A single (1) lymph node is negative for tumor.
- G. Lymph nodes, station 11L set #2, biopsy: A single (1) lymph node is negative for tumor.
- H. Lymph nodes, station 10L, biopsy: Multiple (2) fragments of lymph nodes are negative for tumor.
- I. Lymph nodes, station 7 set #2, biopsy: Multiple (3) fragments of lymph nodes are negative for tumor.
- J. Lymph nodes, station 11L set #3, biopsy: Multiple (3) fragments of lymph nodes are negative for tumor.
- K. Lymph nodes, station 5, biopsy: A single (1) lymph node is negative for tumor.
- L. Lung, left lower lobe, lobectomy: Invasive grade 3 (of 4) adenocarcinoma, forming a 6.6 x 6.2 x 5.8 cm peripheral mass. Visceral pleural invasion is present. Angiolymphatic invasion is absent. The bronchial margin is negative for tumor (by 3.7 cm). [AJCCpT_2_BNOMX]

Frozen section histologic interpretation of station 7 lymph nodes set #1, station 4L lymph nodes and station 4R lymph nodes performed by:

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

ADDENDUM:

At the request of , k-ras mutation analysis will be performed on paraffin-embedded lung tissue (block L4). Upon completion, results will be available in

lw
10/29/12

[page 2 of 4]
Transcribed by:

Signed by

AMENDMENTS: (Previous Signout Date:
Revision Description: Part L in final diagnosis contains
typographical error. AJCC staging should be T2 not T12.
....Original Diagnosis....

A. Lymph nodes, station 7, biopsy: Multiple (6) fragments of lymph
nodes are negative for tumor.

B. Lymph nodes, station 4L, biopsy: A single (1) lymph node is
negative for tumor.

C. Lymph nodes, station 4R, biopsy: A single (1) lymph node is
negative for tumor.

D. Lymph nodes, station 9L set #1, biopsy: A single (1) lymph node
is negative for tumor.

E. Lymph nodes, station 9L set #2, biopsy: Multiple (4) fragments of
lymph nodes are negative for tumor.

F. Lymph nodes, station 11L set #1, biopsy: A single (1) lymph node
is negative for tumor.

G. Lymph nodes, station 11L set #2, biopsy: A single (1) lymph node
is negative for tumor.

H. Lymph nodes, station 10L, biopsy: Multiple (2) fragments of lymph
nodes are negative for tumor.

I. Lymph nodes, station 7 set #2, biopsy: Multiple (3) fragments of
lymph nodes are negative for tumor.

J. Lymph nodes, station 11L set #3, biopsy: Multiple (3) fragments
of lymph nodes are negative for tumor.

K. Lymph nodes, station 5, biopsy: A single (1) lymph node is
negative for tumor.

L. Lung, left lower lobe, lobectomy: Invasive grade 3 (of 4)
adenocarcinoma, forming a 6.6 x 6.2 x 5.8 cm peripheral mass.
Visceral pleural invasion is present. Angiolymphatic invasion is
absent. The bronchial margin is negative for tumor (by 3.7 cm).
[AJCCpT12bnOMX]

Frozen section histologic interpretation of station 7 lymph nodes
set #1, station 4L lymph nodes and station 4R lymph nodes performed
by:

This final pathology report is based on the gross/macrosopic
examination and frozen section histologic evaluation of the
specimen(s). ~~hematoxylin and eosin (H&E) permanent sections are~~
reviewed to confirm these findings. Any substantive changes
identified on permanent section review will be reflected in a
revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "station 7 lymph nodes" is a 2.0 x 1.5 x
0.4 cm aggregate of lymphatic tissue which is entirely submitted.
Grossed by

B. Received fresh labeled "station 4 left lymph nodes" is a 0.5 x
0.5 x 0.3 cm aggregate of lymphatic tissue which is entirely
submitted. Grossed by

[page 3 of 4]
C. Received fresh labeled "station 4 right lymph nodes" is a 1.5 x 1.0 x 0.5 cm aggregate of lymphatic tissue which is entirely submitted. Grossed by

D. Received fresh labeled "station 9 left lymph nodes" is a 0.9 x 0.8 x 0.6 cm aggregate of lymphatic tissue which is entirely submitted. Grossed by

E. Received fresh labeled "station 9 left lymph nodes set #2" is a 1.7 x 1.2 x 0.3 cm aggregate of lymphatic tissue which is entirely submitted. Grossed by

F. Received fresh labeled "station 11 left lymph nodes" is a 0.4 x 0.3 x 0.2 cm aggregate of lymphatic tissue which is entirely submitted. Grossed by

G. Received fresh labeled "station 11 left lymph nodes set #2" is a 1.9 x 1.0 x 0.5 cm aggregate of lymphatic tissue which is entirely submitted. Grossed by

H. Received fresh labeled "station 10 left lymph nodes" is a 2.5 x 1.5 x 0.5 cm aggregate of lymphatic tissue which is entirely submitted. Grossed by

I. Received fresh labeled "station 7 lymph nodes set #2" is a 1.8 x 1.2 x 0.5 cm aggregate of lymphatic tissue which is entirely submitted. Grossed by

J. Received fresh labeled "station 11 left lymph nodes set #3" is a 1.0 x 0.7 x 0.2 cm aggregate of lymphatic tissue which is entirely submitted. Grossed by

K. Received fresh labeled "station 5 lymph nodes" is a 0.7 x 0.5 x 0.3 cm aggregate of lymphatic tissue which is entirely submitted. Grossed by

L. Received fresh labeled "left lung lower lobe" is a 300.0 gram lobectomy. There is a 6.6 x 6.2 x 5.8 cm central, solid mass, located 3.7 cm from the bronchial margin. The mass umbilicates the visceral pleura. Multiple intrapulmonary peribronchial lymph nodes are identified. Representative sections are submitted. Grossed by

BLOCK SUMMARY:

Part A: Station #7 subcarinal lymph nodes

- 1 Subcarinal LN (A1)
- 2 Subcarinal LN (A2)

Part B: station 4 left lower paratracheal lymph node

- 1 Lt low paratracheal LN

Part C: station 4 right lower paratracheal lymph node

- 1 Rt low paratracheal LN

Part D: Station #9 left pulmonary ligament lymph nodes

- 1 Lt pulmonary ligament LN

Part E: Station #9 left pulmonary ligament lymph nodes set #2

- 1 Lt pulmonary ligament LN #2

Part F: station 11 left interlobar lymph node

- 1 Lt interlobar LN

Part G: station 11 left interlobar lymph node #2

- 1 Lt interlobar LN #2

Part H: Station #10 left hilar lymph nodes

- 1 Lt hilar LN
- 2 Lt hilar LN

Part I: Station #7 subcarinal lymph nodes set #2

- 1 Subcarinal LNs #2

[page 4 of 4]
2 Subcarinal LNs #2

Part J: Station #11 left interlobar lymph nodes set #3
1 Lt interlobar LNs #3

Part K: Station #5 subaortic lymph nodes
1 Subaortic LN

Part L: Left lung lower lobe
1 Bronchial margin
2 Peribronchial LNs
3 Left lower lobe lung
4 Left lower lobe lung
5 Left lower lobe lung
6 Left lower lobe lung
7 Left lower lobe lung
8 Left lower lobe lung
9 Lt lower lobe lung normal

Source: NCI Genomic Data Commons file f2ff8887-68d6-44f8-adf5-75861696f433 (TCGA-MP-A4TE.3AC0F53B-A612-484B-9589-699F583F4F1D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).